Somatic mutation profile of tumor specimen 0DRRU0 from CCDI case PBCGSP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 1.3 years (457 days).
Specimen 0DRRU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e408dc9d-12e5-47d4-8840-7c5d54369eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRRTS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de62c787-bb70-4663-bdb0-10f344dc4dea

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Del 2, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC5 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 491/1263 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376716986; called by muse, mutect2, varscan2
- USP17L18 | c.1212del p.K404Nfs*31 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1560541801, COSV101543610; called by pindel, varscan2
- FCGR1B | c.114del p.I39* | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel
- ANO4 | c.2367A>T p.I789= (on ENST00000392977 / NM_001286615.2; = p.I754= on NM_178826.4) | Silent (SNP) | VAF 454/1118 reads (41%) | called by mutect2, varscan2
